Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6379, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6379-01A (Primary Tumor).

[page 1 of 3]
SPECIMENS:

- A. RIGHT PELVIC LYMPH NODES
- B. LEFT PELVIC LYMPH NODES
- C. PROSTATE

SPECIMEN(S):

- A. RIGHT PELVIC LYMPH NODES
- B. LEFT PELVIC LYMPH NODES
- C. PROSTATE

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA/FSB-right and left pelvic lymph nodes: Negative for carcinoma.
Diagnoses called by Dr. to Dr. at [REDACTED]

GROSS DESCRIPTION:

A. RIGHT PELVIC LYMPH NODES

Received fresh labeled with the patient's identification and "right pelvic lymph nodes" is a 3 x 2 x 1 cm piece of soft tissue containing 3 lymph nodes; the largest is inked blue and bisected. Lymph nodes are submitted entirely for frozen section diagnosis in cassette FSA.

B. LEFT PELVIC LYMPH NODES

Received fresh labeled with the patient's identification and "left pelvic lymph nodes" is a 2.5 x 1.7 x 0.8 cm piece of soft tissue containing 3 lymph nodes; the largest is inked blue and bisected. Lymph nodes are submitted entirely for frozen section diagnosis in cassette FSB.

C. PROSTATE

Received fresh labeled with the patient's identification and "prostate" is a 34-g resected prostate gland measuring 4 cm from right lateral to left lateral, 3.6 cm from anterior to posterior, and 2.9 cm from apex to base. The capsule is smooth, red, and intact. Ink code: Anterior-orange, apex-red, base-blue, right lateral-green, left lateral-yellow, posterior-black. After removal of apex and base, the prostate weighs 23 g and has a nodular tan parenchyma. The right seminal vesicle is 2.6 x 1.3 x 0.4 cm and the left is 2.4 x 1.2 x 0.4 cm; they consist of cystic tan tissue. The right vas deferens is 1.7 x 0.6 cm and the left is 1.5 x 0.6 cm; they consist of tubular tan tissue. Tissue is procured (11 Grams); submitted entirely:

- C1: right apex, perpendicular sections
- C2: left apex, perpendicular sections
- C3: level 1, right anterior
- C4: level 1, right posterior
- C5: level 1, left anterior
- C6: level 1, left posterior
- C7: level 2, anterior and right lateral capsule
- C8: level 2, posterior and left lateral capsule
- C9: level 3, right anterior
- C10: level 3, right posterior
- C11: level 3, left anterior
- C12: level 3, left posterior
- C13-C14: right mid base, perpendicular sections
- C15-C16: left mid base, perpendicular sections
- C17-C18: right lateral base, perpendicular sections
- C19-C20: left lateral base, perpendicular sections
- C21: base with right seminal vesicle and vas deferens
- C22: base with left seminal vesicle and vas deferens
- C23: right seminal vesicle and vas deferens
- C24: left seminal vesicle and vas deferens

DIAGNOSIS:

A. LYMPH NODE, RIGHT PELVIC, BIOPSY:

- THREE LYMPH NODES NEGATIVE FOR TUMOR (0/3).

B. LYMPH NODE, LEFT PELVIC, BIOPSY:

- THREE LYMPH NODES NEGATIVE FOR TUMOR (0/3).

C. PROSTATE, PROSTATECTOMY:

- ADENOCARCINOMA OF PROSTATE, GLEASON GRADES 4 + 3 = 7/10, WITH A TERTIARY ELEMENT OF GLEASON PATTERN 5.

[page 2 of 3]
- TUMOR INVADES RIGHT SEMINAL VESICLE
- TUMOR IS PRESENT FOCALLY AT POSTERIOR MARGIN (~2.5 MM AREA OF MARGIN POSITIVITY, SLIDE C21).
- SEE SYNOPTIC REPORT
- CHRONIC PROSTATITIS

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: C: PROSTATE

Location: Left

Right

Posterior lateral

Apical

Anterior

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 15%

Gleason Grade/Sum:: Grade 4 + 3 , Sum 7 /10; Tertiary grade 5

High Grade PIN Present: Yes

Perineural Invasion: Yes

Vascular/Lymphatic Invasion: No

Seminal Vesicle Invasion: Yes

Right

Muscular Wall Invasion: Yes

Lumen Invasion: No

Periprostatic Fat Involved: Indeterminate

Note: PT2 + or PT 2 X is a proposed stage category where there is margin positivity, but no definitive histologic evidence of extraprostatic extension by carcinoma.

Reference:

Bladder Neck Involved: No

Margins Involvement: Yes

Location: Posterior (slide C21)

Linear Distance: Focal (1-10mm)

Frozen Performed: Yes

Post Hormonal Therapy Change: No

Lymph Nodes: Negative Right 0 / 3 Left 0 / 3

Other Pathologic Findings: BPH

Pathological Staging (pTNM): T 3b N 0 M x

Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

pMX: Cannot be assessed

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material: Block C21

Population: Tumor Cells

Stain/Marker:Result: Comment:

CYTOKERATIN AE1/3 Positive

The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of

[page 3 of 3]
[REDACTED]

staining performance and assay validation within the [REDACTED] of the. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristic determined by the

They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Special stains and/or immunohistochemical stains were performed with appropriately stained positive and negative controls.

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Prostate cancer

[REDACTED]

Source: NCI Genomic Data Commons file f28a189c-b13f-4a59-9c46-47c77737baa9 (TCGA-G9-6379.A097CB29-5440-45F9-B261-025603C37CEF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).